Somatic mutation profile of tumor specimen TCGA-G2-A2ES-01A (aliquot TCGA-G2-A2ES-01A-11D-A17V-08) from TCGA case TCGA-G2-A2ES, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 85.7 years (31,293 days).
Specimen TCGA-G2-A2ES-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2aeee1bb-056a-4f82-bc60-b9f0c8c0d372.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G2-A2ES-11A (Solid Tissue Normal), aliquot TCGA-G2-A2ES-11A-31D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0738cee-e8df-433f-a100-34cee5cd65a9

The open-access MAF lists 509 somatic variants for this specimen: 367 protein-altering or splice-affecting, 127 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 305, Silent 127, Nonsense Mutation 18, Splice Site 15, Frame Shift Del 14, Intron 10, Frame Shift Ins 5, In Frame Del 5, Translation Start Site 3, 3'UTR 2, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-2A>T p.X51_splice | Splice Site (SNP) | VAF 14/27 reads (52%) | hotspot (GDC flag); catalogued as CS014762, CS127043, COSV58692638, COSV58692823, COSV58707376; called by muse, mutect2, varscan2
- FBXW7 | c.1154C>A p.T385K (on ENST00000281708 / NM_001349798.2; = p.T305K on NM_018315.5) | Missense Mutation (SNP) | VAF 21/125 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866269762, COSV55908615, COSV99029538; called by muse, mutect2, varscan2
- KDM6A | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | hotspot (GDC flag); catalogued as COSV65037942; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 56/97 reads (58%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AASDH | c.2374C>A p.H792N | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV52705920; called by muse, mutect2, varscan2
- ABCA5 | c.3368C>T p.A1123V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV67016494; called by muse, mutect2, varscan2
- ABCE1 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV56846969; called by muse, mutect2, varscan2
- ABHD10 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV56324978; called by mutect2, varscan2
- ABHD6 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); catalogued as COSV55908417; called by muse, mutect2, varscan2
- ACOT9 | c.356A>T p.D119V | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60537458; called by muse, mutect2, varscan2
- ADAMTS7 | c.572G>C p.R191T | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as COSV66306825; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3142G>A p.D1048N | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV54444903; called by muse, mutect2, varscan2
- ADGRG5 | c.28T>C p.C10R | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV61083102; called by muse, mutect2, varscan2
- ADGRV1 | c.14233C>A p.L4745M | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV67983602; called by muse, mutect2, varscan2
- AFF4 | c.2777A>T p.K926M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54794014; called by muse, mutect2, varscan2
- AK9 | c.3633+6T>C | Splice Region (SNP) | VAF 25/52 reads (48%) | catalogued as COSV58141254; called by muse, mutect2, varscan2
- AKAP8 | c.1777G>A p.G593R | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV54102129; called by muse, mutect2, varscan2
- AKAP9 | c.6223G>C p.E2075Q (on ENST00000359028; = p.E2043Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as rs769680096, COSV62343973; called by muse, mutect2, varscan2
- AKAP9 | c.6307G>A p.E2103K (on ENST00000359028; = p.E2071K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62343979; called by muse, mutect2, varscan2
- AL713999.2 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV55278668; called by muse, mutect2, varscan2
- ALG1 | c.317A>T p.K106I | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749171775, COSV52157355; called by muse, mutect2, varscan2
- ALOX5 | c.733_734insG p.L245Cfs*44 | Frame Shift Ins (INS) | VAF 45/194 reads (23%) | catalogued as COSV65552041; called by mutect2, pindel, varscan2
- ALPK3 | c.3532G>A p.G1178R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs377179290; called by muse, mutect2, varscan2
- ALX4 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.886); catalogued as rs1404064476, COSV61328917, COSV61329449; called by muse, mutect2
- ANKIB1 | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 91/332 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV56060696; called by muse, mutect2, varscan2
- ANKIB1 | c.2746T>G p.L916V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56060705; called by muse, mutect2, varscan2
- ANKRD27 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.294); catalogued as rs1468876650, COSV60130936; called by muse, mutect2, varscan2
- ANKS1B | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV61347021; called by muse, varscan2
- AOPEP | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52917105; called by muse, mutect2, varscan2
- AP1G2 | c.667A>G p.I223V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV58112075; called by muse, mutect2, varscan2
- APAF1 | c.3500C>T p.P1167L (on ENST00000551964 / NM_181861.2; = p.P1113L on NM_001160.3) | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.284); catalogued as rs761865771, COSV59663610; called by muse, mutect2, varscan2
- APH1B | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 92/294 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as COSV56014167; called by muse, varscan2
- AQR | c.1130T>G p.L377R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV50032409; called by muse, mutect2, varscan2
- ARHGAP35 | c.529C>G p.Q177E | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68330612; called by muse, mutect2, varscan2
- ARHGAP45 | c.541G>T p.G181C | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57431172; called by muse, mutect2, varscan2
- ATAD5 | c.4642del p.A1548Lfs*11 | Frame Shift Del (DEL) | VAF 26/118 reads (22%) | catalogued as COSV58973784; called by mutect2, pindel, varscan2
- ATP2C2 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755421600, COSV52294888; called by muse, mutect2, varscan2
- BAIAP3 | c.2037C>G p.I679M | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV50103893, COSV99136228; called by muse, mutect2, varscan2
- BAZ2B | c.3086G>T p.R1029L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54275351; called by muse, mutect2, varscan2
- BCL2L13 | c.485A>C p.Q162P | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV58225545; called by muse, mutect2, varscan2
- BIRC6 | c.1254G>A p.M418I | Missense Mutation (SNP) | VAF 153/293 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV70198335; called by muse, mutect2, varscan2
- BIRC6 | c.10416G>T p.M3472I | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV70198339; called by muse, mutect2, varscan2
- BIRC6 | c.14138G>T p.R4713L | Missense Mutation (SNP) | VAF 122/217 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70195568, COSV70198344; called by muse, mutect2, varscan2
- BRAP | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.87); catalogued as rs916872025, COSV59536325; called by muse, mutect2, varscan2
- BTG2 | c.293G>C p.S98T | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV51855865; called by muse, mutect2, varscan2
- BUD23 | c.787G>A p.G263S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56094837; called by muse, mutect2, varscan2
- C5orf15 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV51548326; called by muse, mutect2, varscan2
- C9 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54676232; called by muse, mutect2, varscan2
- CAMSAP3 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.852); catalogued as rs769934188, COSV50332957; called by muse, mutect2, varscan2
- CAMTA1 | c.4613A>G p.Y1538C | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780867973, COSV57895840; called by mutect2, varscan2
- CAPRIN1 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV58219492; called by muse, mutect2, varscan2
- CARD14 | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV60122985; called by muse, varscan2
- CCDC24 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV62210424; called by muse, mutect2, varscan2
- CCDC24 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 45/136 reads (33%) | catalogued as rs376940328; called by muse, mutect2, varscan2
- CCDC39 | c.8G>T p.S3I | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV56482560; called by muse, varscan2
- CCDC50 | c.1196G>A p.R399Q (on ENST00000392455 / NM_178335.3; = p.R223Q on NM_174908.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs910796129, COSV66667731; called by muse, mutect2, varscan2
- CCDC88C | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV66237289; called by muse, mutect2, varscan2
- CCDC9B | c.1409T>C p.L470P | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1300280612, COSV66875226; called by muse, mutect2, varscan2
- CCM2L | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52950085; called by muse, mutect2, varscan2
- CCP110 | c.115C>T p.H39Y | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV66816867; called by muse, mutect2, varscan2
- CD101 | c.1509C>G p.I503M | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV56717473; called by muse, mutect2, varscan2
- CD1E | c.929T>G p.L310R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63770797; called by muse, mutect2, varscan2
- CDC6 | c.1657A>G p.N553D | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1242607556, COSV52930295; called by muse, mutect2, varscan2
- CENPB | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV60146043; called by muse, mutect2, varscan2
- CENPE | c.4413+2T>A p.X1471_splice | Splice Site (SNP) | VAF 17/73 reads (23%) | catalogued as COSV54380055; called by muse, mutect2, varscan2
- CFAP20DC | c.731G>A p.R244K (on ENST00000482387 / NM_001351530.2; = p.R119K on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV55918847; called by muse, mutect2, varscan2
- CHD1 | c.213A>C p.E71D | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.142); catalogued as COSV52339532; called by muse, mutect2, varscan2
- CHL1 | c.119A>T p.Q40L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV56591291; called by muse, mutect2, varscan2
- CHMP4C | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV51926202; called by muse, mutect2, varscan2
- CHMP6 | c.404A>G p.E135G | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV100289500, COSV57327269; called by muse, mutect2, varscan2
- CHMP7 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1375108708, COSV57532744; called by muse, mutect2, varscan2
- CLDN12 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV55306695; called by muse, mutect2, varscan2
- CLDN17 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54522769; called by muse, mutect2, varscan2
- CLTC | c.4680A>C p.E1560D | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as COSV52246987, COSV52249042; called by muse, mutect2, varscan2
- CNOT1 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as COSV100408983; called by muse, mutect2, varscan2
- CNST | c.968G>T p.S323I | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV63621691; called by muse, mutect2, varscan2
- COL7A1 | c.4837G>A p.G1613R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60394408; called by muse, mutect2, varscan2
- COQ9 | c.685C>G p.H229D | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52645611; called by muse, mutect2, varscan2
- CREBRF | c.1068A>T p.E356D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV51632683; called by muse, mutect2, varscan2
- CRTC3 | c.1235C>A p.T412N | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV51596026; called by muse, mutect2, varscan2
- CSHL1 | c.421G>A p.D141N (on ENST00000309894 / NM_022581.3; = p.D47N on NM_001318.4) | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as COSV51987852; called by muse, mutect2
- CSNK1G1 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV57308720; called by muse, mutect2, varscan2
- DCAF12 | c.146A>T p.Y49F | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV63512295; called by muse, mutect2, varscan2
- DCAF5 | c.2321C>A p.P774H | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV58459912; called by muse, mutect2, varscan2
- DDB2 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs772355051, COSV57038062; called by muse, mutect2, varscan2
- DENND3 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as rs1156932234, COSV52802148; called by muse, mutect2, varscan2
- DHDDS | c.751C>G p.H251D | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV52576318; called by muse, mutect2
- DHX34 | c.1493G>C p.G498A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60895165; called by muse, mutect2, varscan2
- DHX9 | c.1993A>G p.T665A | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1183190812, COSV62359108; called by muse, mutect2
- DIAPH3 | c.3457G>A p.E1153K | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as COSV64961380; called by muse, mutect2, varscan2
- DLGAP1 | c.2879C>T p.T960I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59784979, COSV59798803; called by muse, mutect2, varscan2
- DNAH8 | c.12115G>C p.D4039H | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59440126; called by muse, mutect2, varscan2
- DNAI2 | c.1524G>C p.K508N | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56758195; called by muse, mutect2, varscan2
- DSEL | c.3331C>T p.H1111Y | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.993); catalogued as COSV59490898; called by muse, mutect2, varscan2
- DSG2 | c.643A>C p.K215Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as COSV55198512; called by muse, mutect2, varscan2
- DST | c.7592C>T p.T2531I | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV55009811; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs375315307; called by muse, mutect2, varscan2
- EFCAB13 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747166897, COSV58947776; called by muse, mutect2, varscan2
- EID2 | c.680T>G p.L227R | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66810844; called by muse, mutect2, varscan2
- ELAVL4 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63915520; called by muse, mutect2, varscan2
- ELMO1 | c.488T>A p.V163D | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60302171; called by muse, mutect2, varscan2
- EPB41L4A | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs761599799, COSV54867772; called by muse, mutect2, varscan2
- EPB41L4B | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 84/136 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV65796749; called by muse, mutect2, varscan2
- EPHX2 | c.339G>T p.R113S | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV66844625; called by muse, mutect2, varscan2
- EPS8L1 | c.805G>C p.E269Q (on ENST00000201647 / NM_133180.3; = p.E142Q on NM_017729.3) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770704955, COSV52381505; called by muse, mutect2, varscan2
- ERCC2 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55538682; called by muse, mutect2, varscan2
- EXOC7 | c.1072G>T p.D358Y (on ENST00000335146 / NM_001145297.4; = p.D276Y on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58741234; called by muse, mutect2, varscan2
- FAM216A | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62194739; called by muse, mutect2, varscan2
- FAT2 | c.4235G>A p.R1412K | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV55812664, COSV55818170; called by muse, mutect2, varscan2
- FAT4 | c.8280A>C p.K2760N | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs750907829, COSV58680863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FCGR1A | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs1553751816, COSV64985389; called by muse, mutect2, varscan2
- FERD3L | c.34A>G p.T12A | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs757836312, COSV51762333; called by muse, mutect2, varscan2
- FNDC11 | c.684_692del p.W228_T231delinsC | In Frame Del (DEL) | VAF 69/269 reads (26%) | catalogued as COSV64442704; called by mutect2, pindel, varscan2
- FNIP1 | c.3423-1G>T p.X1141_splice | Splice Site (SNP) | VAF 36/148 reads (24%) | catalogued as COSV57195513; called by muse, mutect2, varscan2
- FRAS1 | c.5900G>A p.R1967K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53605037; called by muse, mutect2, varscan2
- FREM2 | c.1658T>C p.L553S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54835280; called by muse, mutect2, varscan2
- FRYL | c.2531G>A p.S844N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV51945177; called by muse, mutect2, varscan2
- FYTTD1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV54083039; called by mutect2, varscan2
- GABRG3 | c.772A>T p.I258F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as rs753820210, COSV61515953; called by muse, mutect2, varscan2
- GAS7 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.448); catalogued as rs1454406764, COSV71562125; called by muse, mutect2, varscan2
- GMEB2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56606787; called by muse, mutect2, varscan2
- GNB1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66100317; called by muse, mutect2, varscan2
- GNE | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.144); catalogued as rs777071346, COSV67454525; called by muse, mutect2, varscan2
- GPNMB | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1236146268, COSV51698036, COSV51700439; called by muse, mutect2, varscan2
- GPNMB | c.1466-2A>G p.X489_splice (on ENST00000381990 / NM_001005340.2; = p.X477_splice on NM_002510.3) | Splice Site (SNP) | VAF 44/138 reads (32%) | catalogued as COSV51698041; called by muse, mutect2, varscan2
- GPR1 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.038); catalogued as rs1304791236, COSV67976726; called by muse, mutect2, varscan2
- GRIK3 | c.2590G>A p.D864N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.21); catalogued as rs1240292513, COSV66138442; called by muse, mutect2, varscan2
- GRIN2A | c.3433G>A p.V1145M | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs779746293, COSV58025654; called by muse, mutect2, varscan2
- GTF3C1 | c.6124G>A p.E2042K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV62240565; called by muse, mutect2, varscan2
- HNRNPD | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); catalogued as COSV58313469; called by muse, mutect2, varscan2
- HOOK1 | c.770T>C p.L257S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV64618569; called by muse, mutect2, varscan2
- HOXA11 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50052968, COSV50053043; called by muse, mutect2, varscan2
- HSPA4L | c.2218T>C p.C740R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV56544997; called by muse, mutect2, varscan2
- HSPA8 | c.1327T>C p.Y443H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57083693; called by muse, mutect2, varscan2
- HSPG2 | c.8849G>T p.G2950V | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV65933035; called by muse, mutect2, varscan2
- IBA57 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100812773, COSV64510995, COSV64511185; called by muse, mutect2, varscan2
- IFT81 | c.1729C>G p.Q577E | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV54361952; called by muse, mutect2, varscan2
- IGF1R | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs751448541, COSV51280792, COSV51417768; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGF1R | c.2015A>C p.K672T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV51280925; called by muse, mutect2, varscan2
- IGFL4 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs1314308890, COSV66618830; called by muse, mutect2, varscan2
- IGLV3-9 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.678); catalogued as rs745321295; called by muse, varscan2
- IMPG2 | c.2995G>A p.D999N | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51976946; called by muse, mutect2, varscan2
- ING3 | c.966A>T p.L322F | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV59950802; called by muse, mutect2, varscan2
- IQSEC3 | c.3023G>A p.G1008E (on ENST00000538872 / NM_001170738.2; = p.G705E on NM_015232.1) | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV58283857; called by muse, mutect2, varscan2
- ITCH | c.1580_1592del p.D527Gfs*18 (on ENST00000262650 / NM_001257137.3; = p.D486Gfs*18 on NM_031483.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 59/343 reads (17%) | catalogued as COSV52931310; called by mutect2, pindel, varscan2
- ITGA10 | c.3349C>T p.R1117W | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs140404631; called by muse, mutect2, varscan2
- ITPK1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as rs767945252, COSV50894878, COSV50896361; called by muse, mutect2, varscan2
- JAG1 | c.566A>T p.D189V | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV54755930; called by muse, mutect2, varscan2
- KCTD19 | c.2684C>A p.A895D | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58572396, COSV58573523; called by muse, mutect2, varscan2
- KIF6 | c.1626T>A p.S542R | Missense Mutation (SNP) | VAF 138/269 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV54674927; called by muse, mutect2, varscan2
- KRT18 | c.825T>G p.I275M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV66316107; called by muse, mutect2, varscan2
- KRTAP10-6 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100551198, COSV100553559; called by muse, mutect2, varscan2
- LENG9 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV56618045; called by muse, mutect2, varscan2
- LGALS4 | c.835C>G p.R279G | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57043501, COSV57043684; called by muse, mutect2, varscan2
- LIN7C | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs908028442, COSV53415225; called by muse, mutect2, varscan2
- LIPG | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV54295837; called by muse, mutect2, varscan2
- LLGL2 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV51348278; called by muse, varscan2
- LPA | c.5932C>G p.H1978D | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.982); catalogued as COSV60300747, COSV60313831; called by muse, mutect2, varscan2
- LRP5 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780921829, COSV53714391; called by muse, mutect2, varscan2
- LRRC7 | c.3235G>A p.E1079K (on ENST00000651989 / NM_001370785.2; = p.E1046K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV50443412, COSV99224952; called by muse, mutect2, varscan2
- LRRN3 | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57817981; called by muse, mutect2, varscan2
- MACO1 | c.1274T>G p.M425R | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV65476223; called by muse, mutect2, varscan2
- MAPK4 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68541803; called by muse, mutect2, varscan2
- MED12L | c.4877C>T p.P1626L | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56376250; called by muse, mutect2, varscan2
- MEP1B | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52497142; called by muse, mutect2, varscan2
- MID2 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV53308854; called by muse, mutect2, varscan2
- MROH2B | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.137); catalogued as rs1427712030, COSV101270924, COSV68181885, COSV68186148; called by muse, mutect2, varscan2
- MUC15 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV55553923, COSV55553994; called by muse, mutect2, varscan2
- MUC16 | c.22580C>A p.S7527Y | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as COSV67442524, COSV67459123; called by muse, mutect2, varscan2
- MUC17 | c.4019C>G p.T1340R | Missense Mutation (SNP) | VAF 121/443 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs1428572252, COSV60286289; called by muse, mutect2, varscan2
- MUC3A | c.9177G>T p.K3059N | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.412); catalogued as rs973063273, COSV60220140; called by muse, mutect2, varscan2
- MYLK | c.4390T>A p.Y1464N | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60608870; called by muse, mutect2, varscan2
- MYOF | c.3895C>T p.P1299S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV63703087; called by muse, varscan2
- MYOM3 | c.2818C>A p.L940M | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV58392740; called by muse, mutect2, varscan2
- NALCN | c.2533A>T p.R845W | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV51930816; called by muse, mutect2, varscan2
- NASP | c.340C>A p.H114N | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.346); catalogued as COSV63112715; called by muse, mutect2, varscan2
- NBN | c.107A>C p.E36A | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV55372587; called by muse, mutect2, varscan2
- NBPF3 | c.904C>A p.H302N | Missense Mutation (SNP) | VAF 90/373 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV59058563; called by muse, mutect2, varscan2
- NDN | c.666G>A p.W222* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV59361490; called by muse, mutect2, varscan2
- NDUFB9 | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52674812; called by muse, mutect2, varscan2
- NFATC2IP | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57909750; called by muse, mutect2, varscan2
- NIPBL | c.7685+1G>A p.X2562_splice | Splice Site (SNP) | VAF 18/101 reads (18%) | catalogued as COSV56949461, COSV56950365; called by muse, mutect2, varscan2
- NME9 | c.580G>C p.E194Q (on ENST00000333911 / NM_001349024.2; = p.E133Q on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV58618048; called by muse, mutect2, varscan2
- NOM1 | c.1109A>G p.N370S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51979787; called by muse, mutect2, varscan2
- NOTCH2 | c.5692G>A p.D1898N | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV56689431; called by muse, mutect2, varscan2
- NPY5R | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58451731; called by muse, mutect2, varscan2
- NR1D2 | c.1685G>T p.R562L | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV56991561; called by muse, mutect2, varscan2
- NR1I3 | c.694+1G>T p.X232_splice | Splice Site (SNP) | VAF 25/134 reads (19%) | catalogued as COSV63467669; called by muse, mutect2, varscan2
- NSD2 | c.2672A>G p.Y891C | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56389502; called by muse, mutect2, varscan2
- NT5C2 | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.776); catalogued as COSV58415916; called by muse, mutect2, varscan2
- OGA | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 101/393 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV63381499; called by muse, mutect2, varscan2
- OR11L1 | c.473T>A p.L158Q | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV63314158, COSV63314409; called by muse, mutect2, varscan2
- OR1F1 | c.533T>C p.F178S | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58960834; called by muse, mutect2, varscan2
- OR2A4 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs768638353, COSV59575830; called by muse, mutect2, varscan2
- OR2G2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1446574180, COSV60739391; called by muse, mutect2, varscan2
- OR2G3 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV60681432; called by muse, mutect2, varscan2
- OR4K17 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59647906; called by muse, mutect2, varscan2
- OR5AC2 | c.44T>G p.V15G | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV62279345; called by muse, varscan2
- OR7G2 | c.724A>G p.I242V | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as rs770212648, COSV59687797; called by muse, mutect2, varscan2
- OVGP1 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV63858236; called by muse, mutect2, varscan2
- PALLD | c.2326G>A p.E776K (on ENST00000505667 / NM_001166108.2; = p.E759K on NM_016081.4) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV54978794; called by muse, mutect2, varscan2
- PARP8 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.158); catalogued as COSV55859049; called by muse, mutect2, varscan2
- PAXBP1 | c.1328T>G p.F443C | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51608459; called by muse, mutect2, varscan2
- PAXIP1 | c.2914C>A p.L972I | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV66898252; called by mutect2, varscan2
- PCDHA6 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV65343257; called by muse, mutect2, varscan2
- PCSK6 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV59340146; called by mutect2, varscan2
- PDE11A | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 98/190 reads (52%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.957); catalogued as COSV53692354; called by muse, mutect2, varscan2
- PDLIM2 | c.512C>G p.S171C (on ENST00000397760; = p.S421C on NM_021630.6) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV56132408; called by muse, mutect2
- PDZD2 | c.2297C>A p.A766D | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56856473; called by muse, mutect2, varscan2
- PENK | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 109/294 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as COSV59241051; called by muse, mutect2, varscan2
- PEX1 | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV50397188; called by muse, mutect2, varscan2
- PHF6 | c.138+1G>A p.X46_splice | Splice Site (SNP) | VAF 39/77 reads (51%) | catalogued as COSV59699465, COSV59701535; called by muse, mutect2, varscan2
- PIK3AP1 | c.1816C>T p.R606W | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1255769798, COSV59531777; called by muse, mutect2, varscan2
- PIK3CG | c.17A>G p.Y6C | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs757808746, COSV63247692; called by muse, mutect2, varscan2
- PKHD1L1 | c.5978T>C p.V1993A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs1285929897, COSV65741629; called by muse, mutect2, varscan2
- PLA2G6 | c.729T>A p.N243K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV59269242; called by muse, mutect2, varscan2
- PLEKHG6 | c.1723G>T p.D575Y | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV50599585; called by muse, mutect2, varscan2
- PLEKHH2 | c.4143A>C p.L1381F | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56752412; called by muse, mutect2, varscan2
- PLOD2 | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51464025; called by muse, mutect2, varscan2
- PNKP | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs758045226; called by muse, mutect2
- PPP1R12A | c.1463A>G p.D488G | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1360252182, COSV54107601; called by muse, mutect2, varscan2
- PPP2R3A | c.1124A>T p.N375I | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV53862646; called by muse, mutect2, varscan2
- PPP3CA | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs774503546, COSV59922383; called by muse, mutect2, varscan2
- PPP4R4 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs745732168, COSV58553728; called by muse, mutect2, varscan2
- PRDM5 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV53359203; called by muse, mutect2, varscan2
- PSD3 | c.1729G>T p.G577C | Missense Mutation (SNP) | VAF 79/379 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54070113; called by muse, mutect2, varscan2
- PTGS2 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV66568705, COSV66568911; called by muse, mutect2, varscan2
- PUS7L | c.590T>A p.V197E | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61261661; called by muse, mutect2, varscan2
- QRFPR | c.914A>T p.Y305F | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as COSV57676450; called by muse, mutect2, varscan2
- RAD51AP1 | c.640G>A p.E214K (on ENST00000228843 / NM_001130862.2; = p.E197K on NM_006479.5) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV57409602; called by muse, mutect2, varscan2
- RAI14 | c.1015A>G p.I339V | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755427930, COSV54293045; called by muse, mutect2, varscan2
- RAPH1 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 75/143 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100051137, COSV57352490; called by muse, mutect2, varscan2
- RBM46 | c.1514G>A p.G505D | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); catalogued as COSV55978323; called by muse, mutect2, varscan2
- RHBDL3 | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52185606; called by muse, varscan2
- RHPN1 | c.956A>G p.E319G | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.164); catalogued as COSV56646125; called by muse, mutect2, varscan2
- RINT1 | c.895T>A p.S299T | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57558262; called by muse, mutect2, varscan2
- RMDN3 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs372835028; called by muse, mutect2, varscan2
- RPL10A | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as COSV57689668; called by muse, mutect2, varscan2
- RPS6KA1 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV65176024; called by muse, mutect2, varscan2
- RPUSD1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV50100290, COSV50102292; called by muse, mutect2, varscan2
- RSF1 | c.4250C>G p.A1417G | Missense Mutation (SNP) | VAF 49/363 reads (13%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.018); catalogued as COSV57839014; called by muse, mutect2, varscan2
- SEC31A | c.1783A>G p.M595V (on ENST00000355196 / NM_001318120.1; = p.M556V on NM_016211.4) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV52344596; called by muse, mutect2, varscan2
- SGSM2 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as COSV52157420; called by muse, mutect2, varscan2
- SH2D2A | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 103/364 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63884699; called by mutect2, varscan2
- SH2D4A | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV56122242; called by muse, mutect2, varscan2
- SHANK1 | c.5455G>C p.E1819Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.26); catalogued as COSV53248268; called by muse, mutect2, varscan2
- SLC12A1 | c.2181G>T p.E727D | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as COSV66794001; called by muse, mutect2, varscan2
- SLC2A10 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63714313; called by muse, mutect2, varscan2
- SLC35E4 | c.755C>G p.S252C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1243907880, COSV55898948; called by muse, mutect2, varscan2
- SLC36A2 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as COSV58863033; called by muse, mutect2, varscan2
- SLC39A12 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66197423; called by muse, mutect2, varscan2
- SLC47A2 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 70/332 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs766288733, COSV57626546, COSV57626650; called by muse, mutect2, varscan2
- SLITRK3 | c.1567G>C p.A523P | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53847696, COSV53847840; called by muse, mutect2, varscan2
- SLK | c.99_116del p.F33_E39delinsL | In Frame Del (DEL) | VAF 20/115 reads (17%) | catalogued as COSV59825048; called by mutect2, pindel, varscan2
- SMAD9 | c.1357C>G p.L453V (on ENST00000379826 / NM_001127217.3; = p.L416V on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV63204763; called by muse, mutect2, varscan2
- SMARCA4 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60791970; called by muse, varscan2
- SPAG17 | c.6551A>G p.N2184S | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs1340392349, COSV60457235; called by muse, mutect2, varscan2
- SPATA20 | c.1483C>T p.R495W (on ENST00000356488 / NM_001258372.1; = p.R511W on NM_022827.4) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769850236; called by muse, mutect2
- SPTBN5 | c.3263A>T p.Q1088L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV58019565; called by muse, mutect2, varscan2
- SRGAP2 | c.2441G>T p.R814I (on ENST00000624873 / NM_001170637.4; = p.R815I on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs1553377821, COSV55335912, COSV55336143; called by muse, varscan2
- SRP68 | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.025); catalogued as COSV57162291; called by muse, mutect2, varscan2
- SRRM2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV57072042; called by muse, mutect2, varscan2
- SRSF1 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); catalogued as COSV51964810; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.325C>G p.R109G | Missense Mutation (SNP) | VAF 17/91 reads (19%) | PolyPhen benign (0.003); catalogued as rs746598078, COSV59562032, COSV59564346; called by muse, mutect2, varscan2
- STAM2 | c.1184A>G p.Y395C | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV55730707; called by muse, mutect2, varscan2
- STKLD1 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.767); catalogued as COSV64241602; called by muse, mutect2, varscan2
- TACC2 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV57753332; called by muse, mutect2, varscan2
- TBC1D20 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs778512413, COSV62612703; called by muse, mutect2, varscan2
- TCHP | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57165359; called by muse, mutect2, varscan2
- TCHP | c.560A>T p.Y187F | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57165370; called by muse, mutect2, varscan2
- TCP11L1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV57514933; called by muse, mutect2, varscan2
- TENM4 | c.8126G>C p.R2709T | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53623150; called by muse, mutect2, varscan2
- TEP1 | c.5127+1G>T p.X1709_splice | Splice Site (SNP) | VAF 17/72 reads (24%) | catalogued as COSV52991499; called by muse, mutect2, varscan2
- TLR4 | c.252_260+10del p.X84_splice (on ENST00000355622 / NM_138554.5; = p.X44_splice on NM_003266.4) | Splice Site (DEL) | VAF 69/196 reads (35%) | catalogued as COSV62923045; called by mutect2, pindel, varscan2
- TLR5 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.185); catalogued as COSV60558719; called by muse, mutect2, varscan2
- TNFRSF10A | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as COSV55325533; called by muse, mutect2, varscan2
- TNRC18 | c.6886C>G p.L2296V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1419104393, COSV60307148; called by muse, mutect2, varscan2
- TOP2A | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 67/393 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV70732422; called by muse, mutect2, varscan2
- TOP3A | c.153C>G p.D51E | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as COSV58176790; called by muse, mutect2, varscan2
- TOX | c.1032G>C p.K344N | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV63266275; called by muse, mutect2, varscan2
- TRA2A | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as rs1280625191, COSV51716646; called by muse, mutect2, varscan2
- TRIM2 | c.1844G>A p.R615Q (on ENST00000437508; = p.R642Q on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100108043, COSV58632829; called by muse, varscan2
- TRIM2 | c.1870+1G>A p.X624_splice (on ENST00000437508; = p.X651_splice on NM_015271.5 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 28/66 reads (42%) | catalogued as COSV58632293, COSV58632845; called by muse, varscan2
- TRIM67 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs372935882; called by muse, mutect2, varscan2
- TTI2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1167764989, COSV62452431; called by muse, mutect2
- TTLL12 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV53354872; called by muse, mutect2, varscan2
- TTYH2 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 80/275 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs746612010, COSV53909933; called by muse, mutect2, varscan2
- UBR4 | c.10108A>G p.S3370G | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.878); catalogued as COSV64387649; called by muse, mutect2, varscan2
- UBXN6 | c.269A>C p.E90A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV56678810; called by muse, mutect2, varscan2
- UFSP2 | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52991338; called by muse, mutect2, varscan2
- USP48 | c.905A>T p.D302V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57609189; called by muse, mutect2, varscan2
- VPS35L | c.1929+2T>C p.X643_splice | Splice Site (SNP) | VAF 17/74 reads (23%) | catalogued as COSV51981783; called by muse, mutect2, varscan2
- VWF | c.4115T>C p.I1372T | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as CM076587, COSV54617701; called by muse, mutect2, varscan2
- WASHC4 | c.3295G>A p.D1099N | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59889308; called by muse, mutect2, varscan2
- WDFY3 | c.5147A>T p.Q1716L | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV55699151; called by muse, mutect2, varscan2
- WDR93 | c.24G>C p.Q8H | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.562); catalogued as COSV51531752; called by muse, mutect2, varscan2
- WEE2 | c.1445G>A p.R482K | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66878718; called by muse, mutect2, varscan2
- WNK4 | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1567654419, COSV55903719; called by muse, mutect2, varscan2
- XRN1 | c.1035+1G>A p.X345_splice | Splice Site (SNP) | VAF 7/52 reads (13%) | catalogued as COSV53810594; called by muse, mutect2, varscan2
- YTHDC1 | c.1136C>T p.T379M (on ENST00000344157 / NM_001031732.4; = p.T361M on NM_133370.4) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447173446, COSV60009842; called by muse, mutect2, varscan2
- ZC3H12A | c.150G>T p.M50I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV66104067; called by muse, mutect2, varscan2
- ZFP36L1 | c.934A>C p.S312R | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs756918933, COSV60545098; called by muse, mutect2, varscan2
- ZFYVE16 | c.823G>T p.V275F | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs1468503650, COSV62015411; called by muse, mutect2, varscan2
- ZNF101 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs375316779, COSV58908794; called by muse, mutect2, varscan2
- ZNF180 | c.1862C>G p.T621S | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as COSV55420853; called by muse, mutect2, varscan2
- ZNF185 | c.1586G>T p.R529L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV59275472; called by muse, mutect2, varscan2
- ZNF225 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53471467; called by muse, mutect2, varscan2
- ZNF264 | c.251G>A p.C84Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54041579; called by muse, mutect2, varscan2
- ZNF583 | c.1497A>T p.K499N | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52402080; called by muse, mutect2, varscan2
- ZNF708 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV63607264; called by muse, mutect2, varscan2
- ZNRF3 | c.1075C>G p.Q359E (on ENST00000544604 / NM_001206998.2; = p.Q259E on NM_032173.3) | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV60433445; called by muse, mutect2, varscan2
- AC242842.3 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, varscan2
- ADAM2 | c.775G>T p.V259F | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- AMBRA1 | c.1890_1899del p.R631* (on ENST00000458649 / NM_001367468.1; = p.R541* on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by pindel, varscan2
- ARL4A | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRX | c.3955C>G p.Q1319E | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC39 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); called by muse, mutect2
- CCL14 | c.241A>G p.K81E (on ENST00000618404 / NM_032963.4; = p.K97E on NM_032962.4) | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIRBP | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 80/282 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- CLDN19 | c.487_505del p.P163Gfs*119 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | called by mutect2, varscan2
- DNAH1 | c.12488_12492dup p.Y4165Gfs*60 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- DOCK11 | c.591del p.Q197Hfs*49 | Frame Shift Del (DEL) | VAF 34/69 reads (49%) | called by mutect2, varscan2
- EEF1D | c.131G>A p.S44N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ENTPD5 | c.1049del p.L350* | Frame Shift Del (DEL) | VAF 48/260 reads (18%) | called by pindel, varscan2
- FBXW7 | c.1741dup p.Q581Pfs*24 (on ENST00000281708 / NM_001349798.2; = p.Q501Pfs*24 on NM_018315.5) | Frame Shift Ins (INS) | VAF 11/65 reads (17%) | called by mutect2, pindel, varscan2
- FCGBP | c.6784G>A p.G2262S | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- GRIN2C | c.3499C>T p.H1167Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- HEYL | c.80G>C p.S27T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- HTR3B | c.8C>G p.S3* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- ITPR2 | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 28/101 reads (28%) | called by muse, varscan2
- KCNJ3 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 53/105 reads (50%) | called by muse, mutect2, varscan2
- KIAA2026 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 45/76 reads (59%) | called by muse, mutect2, varscan2
- KIF3B | c.874_903del p.Y292_L301del | In Frame Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel
- LTBR | c.196_220del p.T66Afs*22 | Frame Shift Del (DEL) | VAF 23/130 reads (18%) | called by mutect2, pindel
- MBD1 | c.1076_1093del p.K359_G364del (on ENST00000269468 / NM_001323950.1; = p.K336_G341del on NM_015845.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 36/156 reads (23%) | called by mutect2, pindel
- MMP28 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MRPS28 | c.15_30del p.C5Wfs*20 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel
- MS4A2 | c.735A>C p.*245Yext*21 | Nonstop Mutation (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- MTMR12 | c.142+1_142+21del p.X48_splice | Splice Site (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- MYL12A | c.445A>T p.K149* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- NANOS3 | c.310C>T p.H104Y (on ENST00000397555; = p.H123Y on NM_001098622.2) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NOA1 | c.1009_1035del p.Y337_G345del | In Frame Del (DEL) | VAF 20/121 reads (17%) | called by mutect2, pindel
- OR4C13 | c.839del p.L280* | Frame Shift Del (DEL) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- OR4N2 | c.861T>A p.Y287* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | called by muse, mutect2
- OR5AS1 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- PLXNA1 | c.1975_1983delinsGTTGT p.Y659Vfs*63 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by pindel, varscan2*
- PSEN1 | c.549-8_567del p.X183_splice | Splice Site (DEL) | VAF 23/140 reads (16%) | called by mutect2, pindel, varscan2
- PTTG1 | c.92-1_93del p.X31_splice | Splice Site (DEL) | VAF 18/98 reads (18%) | called by mutect2, pindel, varscan2
- RGS9 | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- SCX | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC20A1 | c.-7_30del | Translation Start Site (DEL) | VAF 30/84 reads (36%) | called by mutect2, pindel
- SLC46A1 | c.170A>C p.Y57S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2
- SNPH | c.1088C>G p.S363* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- SPATA12 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- SPRED1 | c.241_284del p.I81* | Frame Shift Del (DEL) | VAF 46/253 reads (18%) | called by mutect2, pindel*
- SUCO | c.1287del p.E430Sfs*14 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | called by mutect2, pindel, varscan2
- TGFBR2 | c.783dup p.K262Qfs*11 | Frame Shift Ins (INS) | VAF 40/108 reads (37%) | called by mutect2, pindel, varscan2
- TGM6 | c.2000C>A p.S667* | Nonsense Mutation (SNP) | VAF 35/137 reads (26%) | called by muse, mutect2, varscan2
- TOP2A | c.1468dup p.I490Nfs*10 | Frame Shift Ins (INS) | VAF 48/242 reads (20%) | called by mutect2, pindel, varscan2
- TRAF4 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 36/108 reads (33%) | called by muse, mutect2, varscan2
- TRAV26-1 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- USP33 | c.2464A>T p.K822* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- USP36 | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- YME1L1 | c.1060G>T p.V354F (on ENST00000326799 / NM_139312.3; = p.V297F on NM_014263.4) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- YTHDC2 | c.3223C>T p.Q1075* | Nonsense Mutation (SNP) | VAF 46/130 reads (35%) | called by muse, varscan2
- ZDHHC19 | c.485_507del p.L162Rfs*93 | Frame Shift Del (DEL) | VAF 29/66 reads (44%) | called by mutect2, pindel, varscan2
- ZNF84 | c.1922_1931del p.S641Ifs*92 | Frame Shift Del (DEL) | VAF 65/261 reads (25%) | called by mutect2, pindel, varscan2
- ACLY | c.3030A>T p.V1010= | Silent (SNP) | VAF 51/170 reads (30%) | catalogued as COSV59861812; called by muse, mutect2, varscan2
- ADAMTS17 | c.780C>T p.V260= | Silent (SNP) | VAF 35/181 reads (19%) | catalogued as COSV51478136; called by muse, mutect2
- AKAP13 | c.2460A>T p.T820= | Silent (SNP) | VAF 78/277 reads (28%) | catalogued as COSV63454501; called by muse, mutect2, varscan2
- ANKS1B | c.15G>A p.Q5= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV61347033; called by muse, varscan2
- ARHGDIB | c.330A>G p.K110= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as COSV57455808; called by muse, mutect2, varscan2
- ARHGEF26 | c.1152G>A p.K384= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV62845708; called by mutect2, varscan2
- ASH1L | c.396G>A p.K132= | Silent (SNP) | VAF 84/389 reads (22%) | catalogued as COSV64207301; called by muse, mutect2, varscan2
- ATP2A1 | c.2721C>T p.I907= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs541644982, COSV62869121; called by muse, mutect2, varscan2
- ATP5F1B | c.561C>T p.I187= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV56260789; called by muse, mutect2, varscan2
- BRWD1 | c.4449G>A p.R1483= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV60894794; called by muse, mutect2, varscan2
- BST1 | c.774C>T p.S258= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV53946400; called by muse, mutect2, varscan2
- C1orf56 | c.21G>A p.A7= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV54846671; called by muse, mutect2, varscan2
- C7orf26 | c.165G>A p.V55= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100253931; called by mutect2, varscan2
- CAMK2G | c.396C>T p.I132= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs1291090817, COSV59479790; called by muse, mutect2, varscan2
- CAPN1 | c.1992G>A p.S664= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs747653455, COSV54198087, COSV99658901; called by muse, mutect2, varscan2
- CCDC170 | c.93G>T p.T31= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV53339583, COSV53340040; called by muse, mutect2, varscan2
- CD5 | c.825G>A p.Q275= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs761591716, COSV61718251; called by muse, mutect2, varscan2
- CDC20B | c.552C>G p.L184= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV57051624; called by muse, mutect2, varscan2
- CDC25C | c.1152C>T p.G384= | Silent (SNP) | VAF 46/158 reads (29%) | catalogued as COSV60399103; called by muse, mutect2, varscan2
- CEP192 | c.4404G>C p.S1468= | Silent (SNP) | VAF 50/168 reads (30%) | catalogued as COSV58062846; called by muse, mutect2, varscan2
- CEP192 | c.5103C>T p.L1701= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as rs752135718, COSV58062854; called by muse, mutect2, varscan2
- CHUK | c.2061A>C p.S687= | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as COSV64917662; called by muse, mutect2, varscan2
- CNNM3 | c.1104G>A p.L368= | Silent (SNP) | VAF 62/117 reads (53%) | catalogued as COSV59709063; called by muse, mutect2, varscan2
- CNTRL | c.339G>A p.K113= | Silent (SNP) | VAF 60/114 reads (53%) | catalogued as COSV53046140; called by muse, mutect2, varscan2
- CREB3L3 | c.558G>A p.S186= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs770643783, COSV50186815; called by muse, mutect2, varscan2
- CYB5D1 | c.183C>T p.I61= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as rs1344487138, COSV54680585; called by muse, varscan2
- DDX19B | c.1439G>A p.*480= | Silent (SNP) | VAF 146/355 reads (41%) | catalogued as rs569358193; called by muse, mutect2, varscan2
- DYNC1H1 | c.1779C>T p.V593= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV64136270; called by muse, mutect2, varscan2
- DYNC1H1 | c.8814T>C p.V2938= | Silent (SNP) | VAF 126/478 reads (26%) | catalogued as COSV64136274; called by muse, mutect2, varscan2
- EBNA1BP2 | c.438G>A p.Q146= | Silent (SNP) | VAF 53/245 reads (22%) | catalogued as COSV52539846; called by muse, mutect2, varscan2
- EPG5 | c.4276C>T p.L1426= | Silent (SNP) | VAF 48/182 reads (26%) | catalogued as rs369111537, COSV56345102; called by muse, varscan2
- EVPL | c.5559C>T p.I1853= | Silent (SNP) | VAF 61/228 reads (27%) | catalogued as COSV56909926; called by muse, mutect2, varscan2
- EXPH5 | c.6G>A p.T2= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV56201240; called by muse, mutect2, varscan2
- FAM155A | c.453C>T p.D151= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV65558758; called by muse, mutect2, varscan2
- FASTKD3 | c.630A>G p.K210= | Silent (SNP) | VAF 46/149 reads (31%) | catalogued as COSV52942964; called by muse, mutect2, varscan2
- FBXO22 | c.744C>T p.I248= | Silent (SNP) | VAF 35/141 reads (25%) | catalogued as rs143480986; called by muse, mutect2, varscan2
- FCSK | c.1386C>T p.F462= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV55369904, COSV99851219; called by muse, mutect2, varscan2
- FPGT | c.1134T>C p.Y378= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV63838429; called by muse, mutect2, varscan2
- FZD1 | c.1185G>A p.Q395= | Silent (SNP) | VAF 34/136 reads (25%) | catalogued as COSV55310064; called by muse, mutect2, varscan2
- GALC | c.93G>A p.L31= | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- GDF9 | c.690T>C p.S230= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs1010013865, COSV51526152; called by muse, mutect2, varscan2
- GNPDA2 | c.756G>A p.V252= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV54946479; called by muse, mutect2, varscan2
- GNS | c.1236C>A p.V412= | Silent (SNP) | VAF 38/131 reads (29%) | catalogued as COSV50694485; called by muse, mutect2, varscan2
- GOLGA3 | c.1581C>T p.L527= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV52629528; called by muse, mutect2, varscan2
- GRIK4 | c.495C>T p.I165= | Silent (SNP) | VAF 95/257 reads (37%) | catalogued as rs980327996, COSV70801779; called by muse, mutect2, varscan2
- HGS | c.2142C>T p.L714= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV61267542; called by muse, mutect2, varscan2
- HK1 | c.654C>T p.G218= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV53856872; called by muse, mutect2, varscan2
- INPPL1 | c.1683C>T p.H561= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV53353250; called by muse, mutect2
- INTS2 | c.486C>T p.F162= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV52152764; called by muse, mutect2, varscan2
- IREB2 | c.453G>A p.Q151= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV51921962; called by muse, mutect2, varscan2
- ITGAM | c.1134C>G p.V378= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV54936357; called by muse, mutect2, varscan2
- JUP | c.537G>A p.L179= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV60277706; called by muse, mutect2, varscan2
- KIFC2 | c.1638C>T p.R546= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs370114230; called by muse, mutect2, varscan2
- KLHDC8A | c.198C>G p.P66= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as COSV65678657; called by muse, mutect2, varscan2
- LLGL2 | c.612C>T p.I204= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV51342396; called by muse, mutect2, varscan2
- LMBRD1 | c.1617G>A p.K539= (on ENST00000649011; = p.K517= on NM_018368.4) | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV65296249; called by muse, mutect2, varscan2
- LPCAT3 | c.51G>T p.G17= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV54645494; called by muse, mutect2, varscan2
- LRBA | c.7890G>A p.L2630= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV63953572; called by muse, mutect2, varscan2
- LRP4 | c.4236A>G p.A1412= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as COSV66135375; called by muse, mutect2, varscan2
- LRRC37A2 | c.402G>A p.K134= | Silent (SNP) | VAF 29/252 reads (12%) | called by mutect2, varscan2
- MAGI3 | c.2625A>G p.P875= | Silent (SNP) | VAF 74/269 reads (28%) | catalogued as COSV56833614; called by muse, mutect2, varscan2
- MAP1S | c.1230C>T p.A410= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs780581015, COSV60723675; called by muse, mutect2, varscan2
- MCTP1 | c.1581A>G p.E527= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs878886553, COSV56512531; called by muse, mutect2, varscan2
- MED16 | c.1966C>A p.R656= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV54125651, COSV99514933; called by muse, mutect2, varscan2
- MRC1 | c.4105T>C p.L1369= | Silent (SNP) | VAF 81/176 reads (46%) | catalogued as rs782024524, COSV99519395; called by muse, mutect2, varscan2
- MTURN | c.294G>A p.G98= | Silent (SNP) | VAF 78/312 reads (25%) | catalogued as COSV61023522; called by muse, mutect2, varscan2
- MX2 | c.2064G>A p.K688= | Silent (SNP) | VAF 55/122 reads (45%) | catalogued as COSV58096154; called by muse, mutect2, varscan2
- NAGPA | c.498G>A p.Q166= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV56569751; called by muse, mutect2, varscan2
- NAXE | c.6C>T p.S2= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV63993314; called by muse, mutect2
- NLRP4 | c.2598G>A p.L866= | Silent (SNP) | VAF 59/237 reads (25%) | catalogued as COSV56712247; called by muse, mutect2, varscan2
- NOTUM | c.522C>T p.N174= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as rs1477031751, COSV68826014; called by muse, mutect2, varscan2
- NPIPB3 | c.450C>G p.L150= | Silent (SNP) | VAF 24/187 reads (13%) | catalogued as COSV70019107; called by muse, mutect2, varscan2
- NSRP1 | c.330A>G p.A110= | Silent (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- OR2A12 | c.900A>G p.L300= | Silent (SNP) | VAF 88/370 reads (24%) | catalogued as COSV68821319; called by muse, mutect2, varscan2
- OR6M1 | c.747C>T p.H249= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs772141013, COSV58432659; called by muse, mutect2, varscan2
- OXT | c.279G>A p.G93= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs781195575, COSV54131895; called by muse, mutect2, varscan2
- PARP14 | c.4773C>T p.H1591= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2
- PARPBP | c.900A>G p.K300= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV59673057; called by muse, mutect2, varscan2
- PCGF6 | c.141T>G p.P47= | Silent (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2
- PCNT | c.1323C>T p.S441= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs756913706, COSV64027284; called by muse, mutect2, varscan2
- PDCD5 | c.27G>A p.L9= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV55678238; called by muse, mutect2, varscan2
- PFDN5 | c.165G>A p.K55= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV54475692; called by muse, mutect2, varscan2
- PITX2 | c.717C>T p.L239= (on ENST00000354925 / NM_001204397.1; = p.L246= on NM_000325.6) | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV60742611; called by muse, mutect2, varscan2
- PKN3 | c.432T>G p.A144= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV52576246, COSV52576445; called by muse, mutect2
- PPFIA3 | c.3276G>A p.Q1092= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV53255159; called by muse, mutect2, varscan2
- PPOX | c.1398A>C p.A466= | Silent (SNP) | VAF 46/241 reads (19%) | catalogued as COSV60527049; called by muse, mutect2, varscan2
- PRPF38A | c.327G>C p.L109= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs375603067; called by muse, mutect2, varscan2
- PRSS36 | c.615C>T p.T205= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV51636864, COSV99191317; called by muse, mutect2, varscan2
- PRX | c.2560C>T p.L854= | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as rs772208597, COSV52527561; called by muse, mutect2, varscan2
- PSMA2 | c.336G>A p.Q112= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as COSV55031195; called by muse, mutect2, varscan2
- PTPN18 | c.525C>T p.T175= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as COSV51558349, COSV51558692; called by muse, mutect2, varscan2
- RBFA | c.39G>T p.A13= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV51533463; called by muse, mutect2, varscan2
- RBM19 | c.2313C>G p.L771= | Silent (SNP) | VAF 118/382 reads (31%) | catalogued as COSV55690908; called by muse, mutect2, varscan2
- RECQL4 | c.2613G>A p.E871= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- RGS22 | c.840A>G p.V280= | Silent (SNP) | VAF 14/268 reads (5%) | catalogued as rs1309503477, COSV62660729; called by muse, mutect2
- RNF112 | c.613A>C p.R205= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV71978784; called by muse, mutect2, varscan2
- SCMH1 | c.1863C>A p.I621= (on ENST00000326197 / NM_001031694.2; = p.I552= on NM_012236.4) | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs754894150, COSV58232168, COSV58234591; called by muse, mutect2, varscan2
- SH2B1 | c.1830T>A p.P610= | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as COSV59462312; called by muse, mutect2, varscan2
- SLC10A6 | c.96C>T p.L32= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs556189080, COSV56721433; called by muse, mutect2, varscan2
- SLC25A44 | c.795G>A p.L265= | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as COSV60771468; called by muse, mutect2, varscan2
- SLC25A46 | c.945A>T p.P315= | Silent (SNP) | VAF 92/328 reads (28%) | catalogued as COSV63506697; called by muse, mutect2, varscan2
- SLC49A3 | c.108C>T p.I36= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV59140092; called by muse, mutect2, varscan2
- SLC8A3 | c.2649G>A p.R883= (on ENST00000381269 / NM_183002.3; = p.R881= on NM_033262.4) | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV53688815; called by muse, mutect2, varscan2
- SLITRK6 | c.135A>C p.L45= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV68389970; called by muse, mutect2, varscan2
- SMG1 | c.4728G>A p.T1576= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs767829543, COSV67170785; called by muse, mutect2, varscan2
- SPTBN5 | c.4005G>A p.L1335= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV58019555; called by muse, mutect2, varscan2
- SRGAP2 | c.2433G>A p.V811= (on ENST00000624873 / NM_001170637.4; = p.V812= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as COSV55336107; called by muse, varscan2
- SVOPL | c.1101C>T p.F367= (on ENST00000419765; = p.F215= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV55989819; called by muse, mutect2, varscan2
- TAOK2 | c.939G>A p.K313= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as rs1229774279, COSV54235066; called by muse, mutect2, varscan2
- TCF25 | c.978C>T p.L326= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs1426392068, COSV54526664; called by muse, mutect2, varscan2
- TGM5 | c.1281C>T p.I427= (on ENST00000220420 / NM_201631.4; = p.I345= on NM_004245.4) | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV55009786; called by muse, mutect2, varscan2
- TNN | c.2292G>A p.L764= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV53425063; called by muse, mutect2, varscan2
- TOMM70 | c.714G>A p.E238= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as rs570670915, COSV52523007; called by muse, mutect2, varscan2
- TONSL | c.3021G>A p.V1007= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs760452559; called by muse, varscan2
- TRIM58 | c.129C>T p.F43= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV63569912; called by muse, mutect2, varscan2
- UBA2 | c.84C>T p.I28= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV55825210; called by muse, mutect2, varscan2
- UBE4B | c.3717C>G p.T1239= (on ENST00000343090 / NM_001105562.3; = p.T1110= on NM_006048.5) | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as COSV53530926; called by muse, mutect2, varscan2
- UPF1 | c.1314G>A p.L438= (on ENST00000599848 / NM_001297549.2; = p.L427= on NM_002911.4) | Silent (SNP) | VAF 17/57 reads (30%) | called by muse, varscan2
- VIM | c.768C>T p.I256= | Silent (SNP) | VAF 70/170 reads (41%) | catalogued as rs377349430; called by muse, mutect2, varscan2
- WRAP73 | c.936T>C p.S312= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as COSV54560905; called by muse, mutect2, varscan2
- XPO1 | c.765G>A p.L255= | Silent (SNP) | VAF 52/78 reads (67%) | catalogued as COSV68945670; called by muse, mutect2, varscan2
- YJU2 | c.519G>A p.L173= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV53605988; called by muse, mutect2, varscan2
- ZADH2 | c.798G>A p.L266= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV59268683; called by muse, mutect2, varscan2
- ZCCHC12 | c.78G>A p.L26= | Silent (SNP) | VAF 45/75 reads (60%) | catalogued as COSV59571456; called by muse, mutect2, varscan2
- ZCCHC3 | c.873G>T p.G291= | Silent (SNP) | VAF 38/151 reads (25%) | catalogued as COSV66643103; called by muse, mutect2, varscan2
- ZNF669 | c.129G>A p.R43= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100594266; called by muse, mutect2, varscan2
- ZP1 | c.252C>T p.V84= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV53924114; called by muse, mutect2, varscan2
- ACSL6 | c.993+95C>A | Intron (SNP) | VAF 10/34 reads (29%) | catalogued as COSV57297287; called by muse, varscan2
- C9orf163 | n.1288_1296del | RNA (DEL) | VAF 42/110 reads (38%) | called by mutect2, varscan2
- CLCN5 | c.17-39124C>T | Intron (SNP) | VAF 14/26 reads (54%) | catalogued as COSV101067124; called by muse, mutect2, varscan2
- FBXW7 | c.502-2358G>A | Intron (SNP) | VAF 13/72 reads (18%) | catalogued as COSV55910394; called by muse, mutect2, varscan2
- MECR | c.756+461A>C | Intron (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- Metazoa_SRP | chr17:18610131 C>T | 5'Flank (SNP) | VAF 67/584 reads (11%) | called by muse, mutect2, varscan2
- PHPT1 | c.*109G>A | 3'UTR (SNP) | VAF 20/89 reads (22%) | catalogued as COSV99915659; called by muse, varscan2
- PLXNA4 | c.1372-87018A>G | Intron (SNP) | VAF 29/119 reads (24%) | catalogued as rs753003028, COSV58119216; called by muse, mutect2, varscan2
- PPP1R12B | c.2491-18718G>C | Intron (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- PRKCB | c.1864-5237G>A | Intron (SNP) | VAF 38/109 reads (35%) | catalogued as COSV100334670, COSV57776094; called by muse, mutect2, varscan2
- SLC7A2 | c.-22-4403T>G | Intron (SNP) | VAF 22/130 reads (17%) | catalogued as COSV50251469; called by muse, mutect2
- TRAM1L1 | c.-1C>T | 5'UTR (SNP) | VAF 19/68 reads (28%) | catalogued as COSV100162221; called by muse, mutect2, varscan2
- TTBK1 | c.1986+6312C>T | Intron (SNP) | VAF 40/69 reads (58%) | catalogued as rs765980032, COSV52490445; called by muse, mutect2, varscan2
- WLS | c.*1G>C | 3'UTR (SNP) | VAF 18/50 reads (36%) | catalogued as rs1389086497, COSV99259589; called by muse, mutect2, varscan2
- ZNF655 | c.137-486A>G | Intron (SNP) | VAF 6/25 reads (24%) | catalogued as COSV53158572; called by muse, mutect2, varscan2
